Somatic mutation profile of tumor specimen C3N-04156-02 (aliquot CPT0251000010) from CPTAC case C3N-04156, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 47.5 years (17,362 days).
Specimen C3N-04156-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77f52398-25ac-4f98-83f0-cbe404ca8aa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04156-71 (Blood Derived Normal), aliquot CPT0251110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26d19955-526d-4814-a213-fa9debfa39d0

The open-access MAF lists 273 somatic variants for this specimen: 172 protein-altering or splice-affecting, 95 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 95, Nonsense Mutation 12, Intron 3, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, 5'UTR 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 61/376 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACTG2 | c.1071G>A p.W357* | Nonsense Mutation (SNP) | VAF 66/390 reads (17%) | catalogued as COSV61827589; called by muse, mutect2, varscan2
- ADAM18 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55845273, COSV55856487; called by muse, mutect2, varscan2
- AOC1 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 22/764 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); catalogued as COSV62866702; called by muse, mutect2
- ARNT2 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 112/397 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs374632017; called by muse, mutect2, varscan2
- BCAS3 | c.422A>T p.N141I | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV66405094; called by muse, mutect2, varscan2
- BRINP1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs751806082, COSV56302273; called by muse, mutect2, varscan2
- C3 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746085199, COSV55578737, COSV99836450; called by muse, mutect2, varscan2
- C4B | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 64/962 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747943993; called by muse, mutect2
- C8orf37 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs149558233; called by muse, mutect2, varscan2
- CAGE1 | c.1426G>A p.E476K (on ENST00000512086; = p.E340K on NM_205864.3) | Missense Mutation (SNP) | VAF 46/581 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866412142, COSV57074675; called by muse, mutect2
- CC2D2A | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as rs1370546657, COSV67503690; called by muse, mutect2, varscan2
- CCDC185 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 72/441 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs1359680074, COSV64820536; called by muse, varscan2
- CPNE5 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 65/539 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs368707119; called by muse, mutect2, varscan2
- CSMD3 | c.2047C>T p.R683C (on ENST00000297405 / NM_001363185.1; = p.R579C on NM_052900.3) | Missense Mutation (SNP) | VAF 57/435 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266203286, COSV52185681; called by muse, mutect2, varscan2
- DNAH6 | c.10469C>T p.S3490F | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as rs1037994635, COSV52882626; called by muse, mutect2, varscan2
- DOCK9 | c.1184C>T p.P395L (on ENST00000376460 / NM_001366676.2; = p.P396L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339423406; called by muse, mutect2, varscan2
- ELFN2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 73/668 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs371574699, COSV68744666; called by muse, mutect2, varscan2
- EPRS1 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 55/429 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs200004369, COSV65097456; called by muse, mutect2, varscan2
- F12 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 44/777 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1307861021; called by muse, mutect2
- FAAH2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.065); catalogued as rs745882755, COSV100887429; called by muse, mutect2, varscan2
- FAM135B | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 78/553 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52709656, COSV52715574, COSV52746385; called by muse, mutect2, varscan2
- FAT3 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99972249; called by muse, mutect2, varscan2
- FUT7 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 61/784 reads (8%) | catalogued as rs755873442, COSV55803054; called by muse, mutect2
- GLI1 | c.1367G>C p.G456A | Missense Mutation (SNP) | VAF 70/569 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV57364495; called by muse, mutect2, varscan2
- GORASP1 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 80/498 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs371898042; called by muse, mutect2, varscan2
- GPATCH8 | c.3838C>T p.P1280S | Missense Mutation (SNP) | VAF 57/461 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs765286148, COSV59196523; called by muse, mutect2, varscan2
- HSPB8 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as rs906998876; called by muse, mutect2, varscan2
- IL27RA | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs1348754243; called by muse, mutect2, varscan2
- KMT2B | c.7336C>T p.R2446* | Nonsense Mutation (SNP) | VAF 60/450 reads (13%) | catalogued as COSV55820343; called by muse, mutect2, varscan2
- KRTAP10-5 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 106/684 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1200897715; called by muse, mutect2, varscan2
- LCOR | c.4222C>A p.P1408T | Missense Mutation (SNP) | VAF 86/475 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV99616985; called by mutect2, varscan2
- LONRF2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66540201; called by muse, mutect2, varscan2
- LRP1B | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67204342; called by muse, mutect2, varscan2
- LRRC15 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 74/510 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs776336334; called by muse, mutect2, varscan2
- LRRC69 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 42/301 reads (14%) | catalogued as rs770840858, COSV59249950; called by muse, mutect2, varscan2
- LVRN | c.1280C>G p.T427S | Missense Mutation (SNP) | VAF 24/423 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63498140; called by muse, mutect2
- LY9 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54433731, COSV54437167; called by muse, mutect2, varscan2
- MCTP1 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 106/440 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766406559, COSV56512581; called by muse, mutect2, varscan2
- MED12L | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 76/491 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as rs769648217; called by muse, mutect2, varscan2
- MGAM | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 125/578 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV72073550; called by muse, mutect2, varscan2
- MMRN1 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV53336185; called by muse, mutect2, varscan2
- MOS | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 70/531 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.433); catalogued as COSV61336868; called by muse, mutect2, varscan2
- MROH2B | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs781540317; called by muse, mutect2, varscan2
- MUC16 | c.18094C>T p.H6032Y | Missense Mutation (SNP) | VAF 78/491 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.06); catalogued as rs567848891, COSV67474560; called by muse, mutect2, varscan2
- MUC17 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 156/558 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100071115, COSV60286491; called by muse, mutect2, varscan2
- MYH7B | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 98/763 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1267784799; called by muse, mutect2, varscan2
- MYH7B | c.4108G>A p.E1370K | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV52684546; called by muse, mutect2, varscan2
- MYLK3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101189057, COSV67366296; called by muse, mutect2, varscan2
- NOX1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs868063945; called by muse, mutect2, varscan2
- NRAP | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100748435; called by muse, mutect2, varscan2
- OLFML3 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 100/597 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs769157852; called by muse, mutect2, varscan2
- OR10G9 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1250262626; called by muse, mutect2, varscan2
- OR10J5 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100604677; called by muse, mutect2, varscan2
- OR13H1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1478904433, COSV100088351; called by muse, mutect2, varscan2
- OR4A15 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 54/455 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV59033505; called by muse, mutect2, varscan2
- OR5D18 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV61736333; called by muse, mutect2, varscan2
- OR9A4 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 72/565 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1554439062; called by muse, mutect2, varscan2
- OTC | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs148660170; called by muse, mutect2, varscan2
- OVCH1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs758226282; called by muse, mutect2, varscan2
- P2RX3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs764311484, COSV54441834; called by muse, mutect2, varscan2
- PAPPA2 | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866866; called by muse, mutect2, varscan2
- PCDH12 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 52/426 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.63); catalogued as rs932328568; called by muse, mutect2, varscan2
- PGLYRP3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51951225; called by muse, mutect2, varscan2
- PKDREJ | c.6227G>C p.R2076P | Missense Mutation (SNP) | VAF 72/726 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53549111; called by muse, mutect2
- RANBP17 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV101206256, COSV66658428; called by muse, mutect2, varscan2
- RASAL2 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62719266; called by muse, mutect2, varscan2
- ROS1 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63861723; called by muse, mutect2, varscan2
- RREB1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 170/601 reads (28%) | catalogued as COSV58561026, COSV58562521; called by muse, mutect2, varscan2
- SCIN | c.809A>G p.N270S (on ENST00000297029 / NM_001112706.3; = p.N23S on NM_033128.3) | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.106); catalogued as COSV51691141; called by muse, mutect2
- SERPINA5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 76/485 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.147); catalogued as rs1289731471, COSV100291580; called by muse, mutect2, varscan2
- SGCZ | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101168548; called by muse, mutect2, varscan2
- SH3BP5 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 72/536 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.956); catalogued as rs1355200319; called by muse, varscan2
- SLC4A4 | c.2158C>T p.P720S (on ENST00000264485 / NM_001098484.3; = p.P676S on NM_003759.4) | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV52641397; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 59/473 reads (12%) | catalogued as rs1401548754; called by muse, mutect2, varscan2
- SULT1C2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs532423626, COSV52266512; called by muse, mutect2, varscan2
- THBS2 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 131/564 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1477357959, COSV64681212; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TNC | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 69/446 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV60790320; called by muse, mutect2, varscan2
- TRIM60 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as COSV104417670, COSV61969898; called by muse, mutect2, varscan2
- TRPC4 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 126/476 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752376988; called by muse, mutect2, varscan2
- TSC22D3 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 39/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59778806; called by muse, mutect2
- TSHZ2 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 51/418 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs749112887, COSV61589512; called by muse, mutect2, varscan2
- TTN | c.27239C>T p.P9080L (on ENST00000591111; = p.P8153L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/294 reads (15%) | PolyPhen probably damaging (0.999); catalogued as rs1359908699, COSV59888049; called by muse, mutect2, varscan2
- UBN2 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 64/595 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99944184; called by muse, mutect2, varscan2
- USH2A | c.6982C>T p.P2328S | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs1346779597; called by muse, mutect2, varscan2
- ZIM3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV54146247; called by muse, mutect2, varscan2
- ZNF219 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 100/684 reads (15%) | catalogued as COSV53878191; called by muse, varscan2
- ZNF878 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs772399888; called by muse, mutect2, varscan2
- ABCA9 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- AKAP10 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 71/466 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- APOB | c.7063C>T p.Q2355* | Nonsense Mutation (SNP) | VAF 55/438 reads (13%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 50/387 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATXN2 | c.2830C>T p.P944S (on ENST00000550104; = p.P784S on NM_002973.4) | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTBD8 | c.1663G>A p.D555N (on ENST00000636805 / NM_001376131.1; = p.D42N on NM_015237.4) | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.086); called by muse, varscan2
- C16orf54 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 116/683 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf33 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 63/560 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CACNA2D4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CALHM1 | c.286T>G p.L96V | Missense Mutation (SNP) | VAF 79/595 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CCDC62 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD163 | c.98T>C p.L33S | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1E | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 61/483 reads (13%) | called by muse, mutect2, varscan2
- CDADC1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHAT | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- CHD9 | c.4361C>G p.T1454R | Missense Mutation (SNP) | VAF 58/395 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CLN3 | c.892T>C p.Y298H (on ENST00000360019 / NM_001286104.2; = p.Y322H on NM_000086.2) | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP4 | c.3743C>T p.A1248V | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- COL4A2 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 202/799 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CYP4F3 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- DNAH3 | c.7504G>C p.V2502L | Missense Mutation (SNP) | VAF 92/614 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DNAH7 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP10 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DVL3 | c.1093A>T p.T365S | Missense Mutation (SNP) | VAF 76/549 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- EIF2S1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EXOC6 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- FAAH2 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FREM1 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FSIP2 | c.7126C>T p.P2376S | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBP3 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLIS2 | c.776-1G>A p.X259_splice | Splice Site (SNP) | VAF 63/472 reads (13%) | called by muse, mutect2, varscan2
- GRIK2 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 52/310 reads (17%) | called by muse, mutect2, varscan2
- HEMGN | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HIF1A | c.2322dup p.P775Tfs*3 | Frame Shift Ins (INS) | VAF 25/206 reads (12%) | called by mutect2, pindel, varscan2
- ITSN1 | c.4549A>G p.K1517E | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- JSRP1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 81/468 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KDM3B | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 160/616 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KHDC1L | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 154/618 reads (25%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 74/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF1A | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 52/401 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MALRD1 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MLLT10 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- NOVA1 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 74/452 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NPBWR1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN3 | c.932C>T p.S311L (on ENST00000557594 / NM_001272020.2; = p.S943L on NM_004796.6) | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- NUDT1 | c.208G>A p.D70N (on ENST00000397048 / NM_198952.1; = p.D47N on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2
- OR4C16 | c.530G>C p.C177S | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52B4 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by muse, mutect2
- OR8H3 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PKP1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 55/394 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PLEKHA4 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 39/428 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- POC1A | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 70/369 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- RAD1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RALGAPA2 | c.3586C>T p.P1196S | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCVRN | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF122 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 67/469 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ROS1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 52/379 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- SELENON | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERPINB2 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 98/455 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SH3BP5 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 72/538 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, varscan2
- SLC4A10 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SMYD4 | c.1102A>G p.T368A | Missense Mutation (SNP) | VAF 13/419 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- SON | c.3377C>T p.S1126F | Missense Mutation (SNP) | VAF 79/460 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPG7 | c.2311A>G p.T771A (on ENST00000268704; = p.T778A on NM_003119.4) | Missense Mutation (SNP) | VAF 19/590 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- SPHKAP | c.3751G>A p.V1251M | Missense Mutation (SNP) | VAF 89/541 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SSU72P8 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 43/470 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.31); called by muse, mutect2
- STEAP4 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 49/599 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- STPG4 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SVEP1 | c.8267T>C p.L2756P | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.576); called by muse, mutect2
- TMEM215 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM37 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 62/518 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRERF1 | c.3315G>A p.M1105I | Missense Mutation (SNP) | VAF 131/559 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TRPC7 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 174/646 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ULK4 | c.3151A>G p.M1051V | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT5A | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 30/671 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XYLT1 | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- YY1 | c.1055C>G p.P352R | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZDHHC13 | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 66/501 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM4 | c.3560C>T p.P1187L | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ZNF236 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF721 | c.10C>T p.H4Y (on ENST00000338977; = p.H16Y on NM_133474.4) | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- ZNF780B | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 66/452 reads (15%) | called by muse, mutect2, varscan2
- ZNF99 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCC6 | c.120C>G p.P40= | Silent (SNP) | VAF 53/509 reads (10%) | called by muse, mutect2, varscan2
- ABCC8 | c.765C>T p.I255= | Silent (SNP) | VAF 123/486 reads (25%) | catalogued as rs753335564, COSV56849772; called by muse, mutect2, varscan2
- ABLIM3 | c.318C>T p.F106= | Silent (SNP) | VAF 50/427 reads (12%) | catalogued as rs765263007, COSV58640003; called by muse, mutect2, varscan2
- ADGRE1 | c.2040C>T p.F680= | Silent (SNP) | VAF 76/467 reads (16%) | catalogued as COSV51680851; called by muse, mutect2, varscan2
- ADGRG4 | c.8139C>T p.Y2713= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as rs760907532; called by muse, mutect2, varscan2
- ADRB1 | c.105C>T p.P35= | Silent (SNP) | VAF 83/541 reads (15%) | catalogued as rs35476499; called by muse, mutect2, varscan2
- ANKS1B | c.87G>A p.G29= | Silent (SNP) | VAF 59/461 reads (13%) | catalogued as rs369308498; called by muse, mutect2, varscan2
- AP4E1 | c.15G>T p.V5= | Silent (SNP) | VAF 48/372 reads (13%) | called by muse, varscan2
- ARHGAP45 | c.855A>G p.A285= | Silent (SNP) | VAF 36/689 reads (5%) | called by muse, mutect2
- ASXL3 | c.5055C>T p.D1685= | Silent (SNP) | VAF 138/524 reads (26%) | catalogued as rs900844131; called by muse, mutect2, varscan2
- BPIFA3 | c.663G>A p.V221= | Silent (SNP) | VAF 77/430 reads (18%) | catalogued as rs139539413, COSV64926027; called by muse, mutect2, varscan2
- C8orf33 | c.48C>T p.G16= | Silent (SNP) | VAF 63/557 reads (11%) | catalogued as rs781239458; called by muse, mutect2, varscan2
- CBX4 | c.1251C>T p.T417= | Silent (SNP) | VAF 85/659 reads (13%) | called by muse, varscan2
- CEP120 | c.2274C>T p.A758= | Silent (SNP) | VAF 62/501 reads (12%) | called by muse, mutect2, varscan2
- CHRNA1 | c.207C>T p.I69= | Silent (SNP) | VAF 94/421 reads (22%) | catalogued as rs745766303; called by muse, mutect2, varscan2
- CIART | c.885C>T p.F295= | Silent (SNP) | VAF 99/571 reads (17%) | called by muse, mutect2, varscan2
- COL14A1 | c.1485C>T p.T495= | Silent (SNP) | VAF 37/218 reads (17%) | called by muse, mutect2, varscan2
- CPXM1 | c.1866C>T p.R622= | Silent (SNP) | VAF 63/402 reads (16%) | catalogued as rs142917655; called by muse, mutect2, varscan2
- CSMD1 | c.6582G>A p.T2194= (on ENST00000520002; = p.T2193= on NM_033225.6) | Silent (SNP) | VAF 49/308 reads (16%) | catalogued as rs1055657160; called by muse, mutect2, varscan2
- CYP4A22 | c.987G>A p.G329= | Silent (SNP) | VAF 74/658 reads (11%) | catalogued as rs150628213, COSV53740631; called by muse, mutect2, varscan2
- DDR1 | c.234G>A p.S78= | Silent (SNP) | VAF 225/832 reads (27%) | catalogued as rs759342778; called by muse, mutect2, varscan2
- DDX21 | c.1293C>T p.I431= | Silent (SNP) | VAF 51/373 reads (14%) | catalogued as COSV62555522; called by muse, mutect2, varscan2
- DLG2 | c.255C>T p.S85= (on ENST00000650630 / NM_001351274.2; = p.S48= on NM_001142699.3) | Silent (SNP) | VAF 68/426 reads (16%) | catalogued as COSV65825280; called by muse, varscan2
- DNAH6 | c.2109G>A p.K703= | Silent (SNP) | VAF 43/439 reads (10%) | catalogued as rs1445033835; called by muse, mutect2
- DOP1A | c.5391C>T p.T1797= | Silent (SNP) | VAF 95/322 reads (30%) | called by muse, mutect2, varscan2
- ERBB2 | c.1455C>T p.L485= | Silent (SNP) | VAF 65/492 reads (13%) | called by muse, mutect2, varscan2
- FBLN2 | c.3396G>A p.T1132= | Silent (SNP) | VAF 101/570 reads (18%) | catalogued as rs756586204; called by muse, mutect2, varscan2
- FBN1 | c.7299C>T p.Y2433= | Silent (SNP) | VAF 22/426 reads (5%) | called by muse, mutect2
- FIBCD1 | c.543C>T p.R181= | Silent (SNP) | VAF 49/429 reads (11%) | called by muse, mutect2, varscan2
- FOLH1 | c.1215G>A p.L405= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as COSV99922508; called by muse, mutect2, varscan2
- FOXR2 | c.438C>T p.I146= | Silent (SNP) | VAF 94/319 reads (29%) | called by muse, mutect2, varscan2
- GALNT8 | c.765G>A p.R255= | Silent (SNP) | VAF 68/478 reads (14%) | catalogued as COSV52894439; called by muse, mutect2, varscan2
- GART | c.2757C>T p.L919= | Silent (SNP) | VAF 76/440 reads (17%) | catalogued as COSV67818044; called by muse, mutect2, varscan2
- GOLGA6L7 | c.345G>A p.R115= | Silent (SNP) | VAF 33/360 reads (9%) | called by muse, mutect2, varscan2
- H3C12 | c.387T>C p.R129= | Silent (SNP) | VAF 25/429 reads (6%) | catalogued as rs1277971991; called by muse, mutect2
- HERC2 | c.7008G>A p.Q2336= | Silent (SNP) | VAF 143/505 reads (28%) | called by muse, mutect2, varscan2
- HPS6 | c.2220G>A p.L740= | Silent (SNP) | VAF 79/509 reads (16%) | called by muse, mutect2, varscan2
- HSD17B2 | c.420G>A p.T140= | Silent (SNP) | VAF 56/404 reads (14%) | catalogued as rs768455795, COSV52276922; called by muse, mutect2, varscan2
- IL17RA | c.2217C>T p.L739= | Silent (SNP) | VAF 81/754 reads (11%) | called by muse, mutect2, varscan2
- ITIH2 | c.1083T>C p.D361= | Silent (SNP) | VAF 56/500 reads (11%) | called by muse, mutect2, varscan2
- ITK | c.1578C>T p.S526= | Silent (SNP) | VAF 126/456 reads (28%) | called by muse, mutect2, varscan2
- KIF24 | c.606C>T p.I202= | Silent (SNP) | VAF 34/303 reads (11%) | called by muse, mutect2, varscan2
- LEPR | c.2937G>A p.Q979= | Silent (SNP) | VAF 69/496 reads (14%) | called by muse, mutect2, varscan2
- MAGEB3 | c.678C>T p.F226= | Silent (SNP) | VAF 77/299 reads (26%) | catalogued as rs760845552; called by muse, mutect2, varscan2
- MDN1 | c.7461G>A p.E2487= | Silent (SNP) | VAF 43/345 reads (12%) | called by muse, mutect2, varscan2
- MEPCE | c.378C>T p.P126= | Silent (SNP) | VAF 64/660 reads (10%) | catalogued as rs911576762; called by muse, mutect2, varscan2
- MGAM2 | c.2461C>T p.L821= | Silent (SNP) | VAF 64/312 reads (21%) | called by muse, mutect2, varscan2
- MIA3 | c.1728C>T p.S576= | Silent (SNP) | VAF 73/466 reads (16%) | called by muse, mutect2, varscan2
- MINK1 | c.2169T>C p.A723= | Silent (SNP) | VAF 103/534 reads (19%) | catalogued as COSV61791718; called by muse, mutect2, varscan2
- MMP25 | c.489C>T p.P163= | Silent (SNP) | VAF 82/583 reads (14%) | catalogued as COSV60678389; called by mutect2, varscan2
- MN1 | c.3484C>T p.L1162= | Silent (SNP) | VAF 82/807 reads (10%) | catalogued as rs762639138; called by muse, mutect2, varscan2
- MRM2 | c.171C>T p.A57= | Silent (SNP) | VAF 172/700 reads (25%) | catalogued as rs761685975; called by muse, mutect2, varscan2
- NEUROD4 | c.708C>T p.S236= | Silent (SNP) | VAF 75/570 reads (13%) | catalogued as rs1362982769, COSV54470759; called by muse, mutect2, varscan2
- NMUR2 | c.1120C>T p.L374= | Silent (SNP) | VAF 143/538 reads (27%) | catalogued as COSV99676911; called by muse, mutect2, varscan2
- NOTCH1 | c.234C>T p.D78= | Silent (SNP) | VAF 40/738 reads (5%) | called by muse, mutect2
- OR14I1 | c.93G>A p.L31= | Silent (SNP) | VAF 63/485 reads (13%) | called by muse, mutect2
- OR51A7 | c.336C>T p.S112= | Silent (SNP) | VAF 63/369 reads (17%) | called by muse, mutect2, varscan2
- OR52B4 | c.624G>A p.T208= | Silent (SNP) | VAF 34/388 reads (9%) | catalogued as rs761882574, COSV68769417; called by muse, mutect2
- PATJ | c.3471G>A p.Q1157= | Silent (SNP) | VAF 45/312 reads (14%) | called by muse, mutect2, varscan2
- PIK3R5 | c.525C>T p.F175= | Silent (SNP) | VAF 68/488 reads (14%) | called by muse, mutect2, varscan2
- PLD6 | c.573C>T p.D191= | Silent (SNP) | VAF 28/556 reads (5%) | catalogued as rs371619441; called by muse, mutect2
- PRKG2 | c.1836G>A p.G612= | Silent (SNP) | VAF 60/445 reads (13%) | called by muse, mutect2, varscan2
- PTH2R | c.279C>T p.F93= | Silent (SNP) | VAF 39/303 reads (13%) | called by muse, mutect2, varscan2
- RGS13 | c.465C>T p.S155= | Silent (SNP) | VAF 40/247 reads (16%) | called by muse, mutect2, varscan2
- RHBDF2 | c.579C>T p.G193= | Silent (SNP) | VAF 65/478 reads (14%) | catalogued as rs1218837297; called by muse, varscan2
- SCN9A | c.2814C>T p.V938= (on ENST00000303354; = p.V927= on NM_002977.3) | Silent (SNP) | VAF 64/505 reads (13%) | catalogued as rs373586941; called by muse, mutect2, varscan2
- SFI1 | c.2679C>T p.L893= (on ENST00000400288 / NM_001007467.3; = p.L862= on NM_014775.4) | Silent (SNP) | VAF 190/646 reads (29%) | catalogued as rs778728324, COSV63475721; called by muse, mutect2, varscan2
- SFXN1 | c.129A>G p.Q43= | Silent (SNP) | VAF 41/585 reads (7%) | called by muse, mutect2
- SHH | c.330C>T p.A110= | Silent (SNP) | VAF 108/447 reads (24%) | catalogued as rs552960040, COSV51919383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A7 | c.84C>T p.I28= | Silent (SNP) | VAF 87/616 reads (14%) | catalogued as rs985167612, COSV65194328; called by muse, mutect2, varscan2
- SLC39A5 | c.78C>T p.V26= | Silent (SNP) | VAF 92/649 reads (14%) | catalogued as COSV57192500; called by muse, mutect2, varscan2
- SLC6A12 | c.1158C>T p.I386= | Silent (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2
- SMC1B | c.1479G>A p.E493= | Silent (SNP) | VAF 63/479 reads (13%) | catalogued as rs372093171; called by muse, mutect2, varscan2
- SNRK | c.543C>T p.S181= | Silent (SNP) | VAF 40/289 reads (14%) | catalogued as rs540689823; called by muse, mutect2, varscan2
- SOHLH1 | c.600G>A p.T200= | Silent (SNP) | VAF 42/726 reads (6%) | catalogued as rs374493888; called by muse, mutect2
- TACR2 | c.450G>A p.A150= | Silent (SNP) | VAF 86/565 reads (15%) | catalogued as rs202091754; called by muse, mutect2, varscan2
- TAF1L | c.864G>A p.L288= | Silent (SNP) | VAF 88/656 reads (13%) | called by muse, mutect2, varscan2
- TCAIM | c.507C>T p.S169= | Silent (SNP) | VAF 67/430 reads (16%) | called by muse, mutect2, varscan2
- TCF4 | c.633C>T p.F211= | Silent (SNP) | VAF 24/404 reads (6%) | catalogued as rs776969005, CM155392, COSV61903322; called by muse, mutect2
- TCP10L | c.39G>A p.E13= | Silent (SNP) | VAF 62/505 reads (12%) | catalogued as rs752304742; called by muse, mutect2, varscan2
- TGIF2LY | c.192C>T p.I64= | Silent (SNP) | VAF 65/250 reads (26%) | catalogued as rs1440795101, COSV100339598; called by muse, mutect2, varscan2
- TLE7 | c.1167G>A p.A389= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as rs922756317; called by muse, mutect2, varscan2
- TMTC1 | c.243G>A p.K81= | Silent (SNP) | VAF 80/570 reads (14%) | called by muse, varscan2
- TNXB | c.3870C>T p.I1290= (on ENST00000647633; = p.I1043= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/368 reads (25%) | called by muse, mutect2, varscan2
- TRIM72 | c.1323C>T p.F441= | Silent (SNP) | VAF 65/555 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.5199G>A p.T1733= (on ENST00000591111; = p.T1687= on NM_003319.4) | Silent (SNP) | VAF 90/548 reads (16%) | catalogued as rs1244676379, COSV100600655, COSV59901276; called by muse, mutect2, varscan2
- USP29 | c.1491G>A p.R497= | Silent (SNP) | VAF 39/282 reads (14%) | called by muse, mutect2, varscan2
- USP43 | c.558C>T p.A186= | Silent (SNP) | VAF 72/469 reads (15%) | called by muse, mutect2, varscan2
- VEGFC | c.96C>T p.F32= | Silent (SNP) | VAF 96/554 reads (17%) | catalogued as rs1388348074, COSV54604692; called by mutect2, varscan2
- WBP1L | c.372C>T p.A124= | Silent (SNP) | VAF 80/474 reads (17%) | called by muse, mutect2, varscan2
- ZBBX | c.915A>C p.P305= | Silent (SNP) | VAF 28/271 reads (10%) | catalogued as rs745457056; called by muse, mutect2, varscan2
- ZFP90 | c.1782C>T p.T594= | Silent (SNP) | VAF 57/462 reads (12%) | called by muse, mutect2, varscan2
- ZMYM4 | c.3561C>T p.P1187= | Silent (SNP) | VAF 45/320 reads (14%) | called by muse, mutect2, varscan2
- ZNF536 | c.2838C>T p.S946= | Silent (SNP) | VAF 101/535 reads (19%) | catalogued as COSV62824682; called by muse, mutect2, varscan2
- ZNF845 | c.1611C>T p.S537= | Silent (SNP) | VAF 66/415 reads (16%) | called by muse, mutect2, varscan2
- ANK3 | c.2738+321A>G | Intron (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- BRSK1 | c.-210G>A | 5'UTR (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- DUSP15 | c.426+1023C>A | Intron (SNP) | VAF 34/739 reads (5%) | catalogued as rs769971947; called by muse, mutect2
- PML | c.1710+996C>T | Intron (SNP) | VAF 103/747 reads (14%) | called by muse, mutect2, varscan2
- PRORY | n.471G>A | RNA (SNP) | VAF 79/246 reads (32%) | catalogued as rs1164427181; called by muse, mutect2, varscan2
- XIRP2 | c.*309G>A | 3'UTR (SNP) | VAF 52/426 reads (12%) | catalogued as rs866366674, COSV54732556; called by muse, mutect2, varscan2
